Somatic mutation profile of tumor specimen TCGA-G3-AAV4-01A (aliquot TCGA-G3-AAV4-01A-11D-A382-10) from TCGA case TCGA-G3-AAV4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 83.4 years (30,466 days).
Specimen TCGA-G3-AAV4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27221c82-e553-440d-9f46-429a4880b2d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV4-10A (Blood Derived Normal), aliquot TCGA-G3-AAV4-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8387af2-1d0e-4249-b99f-f4b9294bd279

The open-access MAF lists 122 somatic variants for this specimen: 87 protein-altering or splice-affecting, 32 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 32, Splice Site 5, Nonsense Mutation 4, Splice Region 3, Frame Shift Del 2, In Frame Del 2, 3'UTR 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 67/139 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- TP53 | c.672G>A p.E224= | Splice Region (SNP) | VAF 39/52 reads (75%) | catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- A4GALT | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs549273376, COSV50744204; called by muse, mutect2, varscan2
- ABCG5 | c.1002T>G p.I334M | Missense Mutation (SNP) | VAF 99/166 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99575486; called by muse, mutect2, varscan2
- AMOTL2 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV99998238; called by muse, mutect2, varscan2
- APEX2 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV58193353; called by muse, mutect2, varscan2
- APOB | c.8670C>A p.F2890L | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as COSV51936647; called by muse, mutect2, varscan2
- ARHGEF4 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100388369; called by muse, mutect2
- ARID2 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 66/169 reads (39%) | catalogued as COSV100536310; called by muse, mutect2, varscan2
- ATOX1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs752342635, COSV100491636; called by muse, mutect2, varscan2
- BCAP31 | c.715G>A p.G239S | Missense Mutation (SNP) | VAF 66/192 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.024); catalogued as COSV99466050; called by muse, mutect2, varscan2
- C17orf75 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV99858709; called by muse, mutect2, varscan2
- CAPN7 | c.521G>C p.R174T | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99512920; called by muse, mutect2, varscan2
- CDC42EP1 | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as rs1474373667, COSV99312569; called by muse, mutect2
- CEP290 | c.7095C>A p.N2365K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV100469140; called by muse, mutect2, varscan2
- CMPK2 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs754020979, COSV56774556; called by muse, mutect2, varscan2
- CNGA3 | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV55622943, COSV99737058; called by muse, mutect2, varscan2
- DIAPH1 | c.2858T>G p.I953S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99526856; called by muse, mutect2, varscan2
- DLG1 | c.708C>A p.F236L | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100015594, COSV58388772; called by muse, mutect2, varscan2
- DMRT3 | c.1123A>G p.T375A | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as COSV99505961; called by muse, mutect2, varscan2
- DNAH8 | c.11948C>T p.T3983I | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as COSV100546190; called by muse, mutect2, varscan2
- DOC2A | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100451324; called by muse, mutect2, varscan2
- DOCK2 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99913602; called by muse, mutect2, varscan2
- DST | c.1831C>A p.L611I (on ENST00000361203 / NM_001374722.1; = p.L285I on NM_001723.6) | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55035171; called by muse, mutect2, varscan2
- EGFL7 | c.560C>A p.P187H | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100452015; called by muse, mutect2, varscan2
- FASN | c.6937G>A p.V2313M | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1221950924, COSV100148023; called by muse, varscan2
- FBXO10 | c.1774A>T p.T592S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV99446920; called by muse, mutect2, varscan2
- FGF12 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 53/112 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV99282177; called by muse, mutect2, varscan2
- FGFRL1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 62/104 reads (60%) | catalogued as COSV99294730; called by muse, mutect2, varscan2
- FLG | c.2303C>A p.A768D | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs764517654, COSV100911755, COSV64241712; called by muse, mutect2, varscan2
- FLVCR1 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 215/453 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs138069386, COSV100875085; called by muse, mutect2, varscan2
- FRZB | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99717450; called by muse, mutect2, varscan2
- GLI2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as rs768192957, COSV58051221; called by muse, mutect2, varscan2
- GRM8 | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1193307778, COSV100284232; called by muse, mutect2, varscan2
- HAS1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV99708474; called by muse, mutect2, varscan2
- INTS7 | c.371+1G>A p.X124_splice | Splice Site (SNP) | VAF 106/206 reads (51%) | catalogued as COSV100877531; called by muse, mutect2, varscan2
- JAM3 | c.856G>A p.G286R | Missense Mutation (SNP) | VAF 142/250 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs763891551, COSV100138319, COSV54453382; called by muse, mutect2, varscan2
- KASH5 | c.336G>A p.G112= | Splice Region (SNP) | VAF 15/31 reads (48%) | catalogued as rs1014017883, COSV101483470; called by muse, mutect2, varscan2
- KIF5C | c.2459A>G p.D820G | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV68481781; called by muse, mutect2, varscan2
- LRRTM1 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 105/207 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV54439053; called by muse, mutect2, varscan2
- LSG1 | c.1445T>G p.V482G | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99503353; called by muse, mutect2, varscan2
- LY75 | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV99716664; called by muse, mutect2, varscan2
- MAP3K19 | c.3209G>T p.G1070V | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100208837; called by muse, varscan2
- MCM7 | c.32-2A>G p.X11_splice | Splice Site (SNP) | VAF 64/152 reads (42%) | catalogued as rs762955038, COSV57997571; called by muse, mutect2, varscan2
- MMS22L | c.3263G>T p.R1088L | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs149054595, COSV99247287; called by muse, mutect2, varscan2
- MS4A8 | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100282585; called by muse, mutect2, varscan2
- MUC16 | c.20750T>A p.M6917K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV101200377; called by muse, mutect2, varscan2
- MUC17 | c.8285C>A p.P2762Q | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.937); catalogued as COSV100074089; called by muse, mutect2, varscan2
- MYH15 | c.3817G>A p.A1273T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.99); PolyPhen benign (0.01); catalogued as rs1171272569, COSV99843723; called by muse, mutect2, varscan2
- NUP133 | c.183G>A p.R61= | Splice Region (SNP) | VAF 44/114 reads (39%) | catalogued as rs1161184895, COSV99773145; called by muse, mutect2, varscan2
- PARP4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as COSV101131787, COSV67962312; called by muse, mutect2, varscan2
- PCDH15 | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as COSV100223457; called by muse, mutect2, varscan2
- PCDHGA4 | c.1481A>C p.E494A | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99541754; called by muse, mutect2, varscan2
- PGAP1 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 363/812 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as COSV100698275; called by muse, mutect2, varscan2
- PGM5 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101123491; called by muse, mutect2, varscan2
- PIK3C2B | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.314); catalogued as rs748272390, COSV100915050; called by muse, mutect2, varscan2
- PKN2 | c.1202A>G p.N401S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100281669; called by muse, mutect2, varscan2
- PLRG1 | c.1151+2T>C p.X384_splice | Splice Site (SNP) | VAF 51/88 reads (58%) | catalogued as COSV100123164; called by muse, mutect2, varscan2
- PRDM10 | c.547G>T p.A183S | Missense Mutation (SNP) | VAF 129/271 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100456874; called by muse, mutect2, varscan2
- PRDM8 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100325226; called by muse, mutect2, varscan2
- ROBO1 | c.2680G>A p.V894M | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101458954; called by muse, mutect2, varscan2
- SEMA3C | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99543316; called by muse, mutect2, varscan2
- SETDB1 | c.3702T>G p.N1234K | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99645203; called by muse, mutect2, varscan2
- SHANK1 | c.4745C>A p.S1582* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV99521547; called by muse, mutect2, varscan2
- SPACA3 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs143361724; called by muse, mutect2, varscan2
- STON1 | c.1409A>G p.Y470C | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as COSV100562003; called by muse, mutect2, varscan2
- TBL3 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 52/95 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100224965; called by muse, mutect2, varscan2
- TCF20 | c.3286G>T p.E1096* | Nonsense Mutation (SNP) | VAF 42/98 reads (43%) | catalogued as COSV100166752; called by muse, mutect2, varscan2
- TM9SF2 | c.938T>A p.F313Y | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100899729; called by muse, mutect2, varscan2
- TPX2 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100301876; called by muse, mutect2
- TRPM8 | c.299C>A p.T100N | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100224265; called by muse, mutect2, varscan2
- USP20 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); catalogued as COSV100204469; called by muse, mutect2, varscan2
- UTP20 | c.6898A>G p.R2300G | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99881983; called by muse, varscan2
- VPS9D1 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1471800266, COSV101232018; called by muse, mutect2
- ZEB2 | c.1397T>C p.I466T | Missense Mutation (SNP) | VAF 92/188 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100356415; called by muse, mutect2, varscan2
- ZNF302 | c.1183C>T p.R395C (on ENST00000627982; = p.R316C on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs528898854, COSV101416507; called by muse, mutect2, varscan2
- ZNF304 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV99988718; called by muse, mutect2, varscan2
- ZNF383 | c.939G>C p.K313N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.863); catalogued as COSV100776772; called by muse, mutect2, varscan2
- ZNF587 | c.263C>G p.P88R | Missense Mutation (SNP) | VAF 41/242 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV100299578; called by muse, mutect2, varscan2
- ZNF628 | c.2761G>T p.D921Y | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1238023425, COSV99220157; called by muse, mutect2, varscan2
- ZNF653 | c.1571G>A p.G524D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV99542213; called by muse, mutect2
- ABHD11 | c.254_263del p.I85Tfs*11 | Frame Shift Del (DEL) | VAF 63/147 reads (43%) | called by mutect2, pindel, varscan2
- ARID2 | c.773-3_797del p.X258_splice | Splice Site (DEL) | VAF 49/167 reads (29%) | called by mutect2, pindel, varscan2
- BTN1A1 | c.881-18_883del p.X294_splice | Splice Site (DEL) | VAF 42/113 reads (37%) | called by pindel, varscan2
- GPR4 | c.193_216del p.L65_L72del | In Frame Del (DEL) | VAF 33/100 reads (33%) | called by mutect2, pindel, varscan2
- IFIT2 | c.928_942del p.R310_E314del | In Frame Del (DEL) | VAF 14/81 reads (17%) | called by pindel, varscan2
- ZDHHC19 | c.858del p.S287Lfs*66 | Frame Shift Del (DEL) | VAF 71/159 reads (45%) | called by mutect2, pindel, varscan2
- ABCA13 | c.5757A>G p.K1919= | Silent (SNP) | VAF 93/185 reads (50%) | catalogued as COSV101330106; called by muse, mutect2, varscan2
- ANKRD24 | c.423G>A p.V141= | Silent (SNP) | VAF 99/235 reads (42%) | catalogued as rs1181865255, COSV99517791; called by muse, mutect2, varscan2
- ASB11 | c.828G>A p.Q276= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV100729075; called by muse, mutect2, varscan2
- C19orf33 | c.315C>T p.P105= | Silent (SNP) | VAF 78/358 reads (22%) | catalogued as COSV100007986; called by muse, mutect2, varscan2
- C2orf42 | c.1347C>T p.T449= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as COSV100033999; called by muse, mutect2, varscan2
- C9orf24 | c.609C>A p.G203= | Silent (SNP) | VAF 33/55 reads (60%) | catalogued as rs778876533, COSV99898022; called by muse, mutect2, varscan2
- DNAH2 | c.7059G>A p.T2353= | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as rs779175874, COSV101209479; called by muse, mutect2, varscan2
- DNER | c.1398C>T p.A466= | Silent (SNP) | VAF 158/355 reads (45%) | catalogued as COSV100519508; called by muse, mutect2, varscan2
- DOCK2 | c.4494C>T p.A1498= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as COSV99913604; called by muse, mutect2, varscan2
- EGFL7 | c.561C>A p.P187= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as COSV100452017; called by muse, mutect2, varscan2
- EXTL1 | c.456A>G p.Q152= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs758644180, COSV100959091; called by muse, mutect2, varscan2
- FBN2 | c.8529C>T p.S2843= | Silent (SNP) | VAF 68/137 reads (50%) | catalogued as rs140437100; called by muse, mutect2, varscan2
- FLNC | c.3693C>T p.G1231= | Silent (SNP) | VAF 44/103 reads (43%) | catalogued as rs765922145, COSV57955334; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- HECTD3 | c.2244G>A p.E748= | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs1488462723, COSV100938159; called by muse, mutect2, varscan2
- IGHV3-35 | c.72G>T p.V24= | Silent (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- KTN1 | c.3639A>G p.L1213= (on ENST00000395314 / NM_001271014.2; = p.L1184= on NM_004986.4) | Silent (SNP) | VAF 94/221 reads (43%) | catalogued as COSV100618339; called by muse, mutect2, varscan2
- LRRC7 | c.558C>T p.A186= (on ENST00000651989 / NM_001370785.2; = p.A153= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as COSV99227998; called by muse, mutect2, varscan2
- MAGEB10 | c.378C>T p.Y126= | Silent (SNP) | VAF 139/251 reads (55%) | catalogued as COSV100775325; called by muse, mutect2, varscan2
- MAML2 | c.3225C>T p.G1075= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV101594152; called by muse, mutect2, varscan2
- MDC1 | c.6192C>T p.F2064= | Silent (SNP) | VAF 61/226 reads (27%) | catalogued as COSV100902955; called by muse, mutect2, varscan2
- NDC1 | c.1848C>T p.P616= | Silent (SNP) | VAF 56/146 reads (38%) | catalogued as rs758542055, COSV52337394; called by muse, mutect2, varscan2
- PCSK5 | c.1122G>A p.L374= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100950362; called by muse, mutect2, varscan2
- PIP5KL1 | c.681C>T p.R227= (on ENST00000388747 / NM_001135219.2; = p.R24= on NM_173492.1) | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100304888; called by muse, mutect2, varscan2
- PLEKHH1 | c.429G>A p.E143= | Silent (SNP) | VAF 84/151 reads (56%) | catalogued as COSV100233300; called by muse, mutect2, varscan2
- PPP2R2A | c.789T>C p.D263= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV100277275; called by muse, mutect2, varscan2
- PRDM15 | c.3417G>A p.Q1139= | Silent (SNP) | VAF 68/121 reads (56%) | catalogued as COSV99520429; called by muse, mutect2, varscan2
- PRRC2B | c.1098C>G p.A366= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV100621941; called by muse, mutect2, varscan2
- RCVRN | c.39C>A p.I13= | Silent (SNP) | VAF 37/41 reads (90%) | catalogued as COSV99874244; called by muse, mutect2, varscan2
- SPARCL1 | c.1482G>T p.G494= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as rs995267082, COSV56804906, COSV99215723; called by muse, mutect2, varscan2
- SYNRG | c.1953T>A p.S651= | Silent (SNP) | VAF 38/88 reads (43%) | called by muse, mutect2, varscan2
- TAF1 | c.426C>T p.P142= | Silent (SNP) | VAF 33/110 reads (30%) | catalogued as COSV99336301; called by muse, mutect2, varscan2
- ZPBP | c.222C>T p.V74= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as rs1217317082, COSV50439144; called by muse, mutect2, varscan2
- FAM183BP | n.943G>T | RNA (SNP) | VAF 58/124 reads (47%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-86033G>A | Intron (SNP) | VAF 17/67 reads (25%) | catalogued as COSV72282937; called by muse, mutect2
- POMGNT1 | c.*346C>A | 3'UTR (SNP) | VAF 36/89 reads (40%) | catalogued as COSV100915682, COSV100915687; called by muse, mutect2, varscan2
